Gene-level copy-number profile of tumor specimen TCGA-DK-A3IN-01A from TCGA case TCGA-DK-A3IN, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 72.7 years (26,562 days).
Specimen TCGA-DK-A3IN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.bfb1cb65-9c62-422f-b5ed-2f0e322e592a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A3IN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/03466c0b-147f-43d4-b2ad-a700ecc9a9d4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 67; copy number 2: 13,260; copy number 3: 19,676; copy number 4: 19,754; copy number 5: 3,338; copy number 6: 1,430; copy number 7: 1,026; copy number 8: 373; copy number 9: 146; copy number 10: 192; copy number 11: 193; copy number 12: 51; copy number 13: 135; copy number 14: 5; copy number 15: 5; copy number 17: 4; copy number 18: 89; copy number 23: 46; copy number 26: 1; copy number 27: 2; copy number 33: 7; copy number 59: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A3IN-01A-11D-A20B-01): tumor purity 0.39, ploidy 3.57, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 894 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:111,250,254–111,256,715, 1 gene, copy number 11: CHIAP1.
- chr1:117,493,515–117,495,006, 1 gene, copy number 14: AL157902.2.
- chr1:172,138,397–172,213,499, 5 genes, copy number 11: DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1.
- chr2:56,750,300–56,750,563, 1 gene, copy number 14: PPIAP63.
- chr2:76,985,965–77,009,791, 1 gene, copy number 13 (within-gene range 4–13): LRRTM4-AS1.
- chr2:145,294,277–145,338,057, 2 genes, copy number 9: AC096666.1, RPL6P5.
- chr2:178,577,103–178,645,179, 4 genes, copy number 18: AC010680.3, AC010680.2, AC010680.4, AC010680.5.
- chr3:53,348–12,788,671, 184 genes, copy number 11–59 (broad region; genes not listed).
- chr3:18,445,024–18,920,401, 1 gene, copy number 13 (within-gene range 6–13): SATB1-AS1.
- chr3:30,292,548–31,269,406, 13 genes, copy number 9–15: AC025614.2, AC025614.1, U3, LINC01985, AC116035.1, TGFBR2, AC096921.1, AC096921.2, GADL1, MIR466, CNN2P6, RNA5SP127, H3P11.
- chr5:53,297,872–53,326,565, 1 gene, copy number 11: AC027329.1.
- chr7:8,433,609–8,752,961, 1 gene, copy number 10 (within-gene range 6–10): NXPH1.
- chr7:62,275,361–62,275,678, 1 gene, copy number 11: AC128676.1.
- chr7:78,939,850–78,940,895, 1 gene, copy number 14: MAGI2-AS1.
- chr7:121,194,948–121,195,057, 1 gene, copy number 12: RNU6-517P.
- chr8:5,072,645–5,072,869, 1 gene, copy number 9: AC019176.1.
- chr8:43,672,823–43,674,591, 2 genes, copy number 14: AC139365.2, AC139365.1.
- chr10:85,526,880–85,557,436, 3 genes, copy number 12: AL731532.1, RNU6-325P, AL731532.2.
- chr11:21,383,801–21,843,210, 2 genes, copy number 11 (within-gene range 5–11): RNA5SP337, AC130307.1.
- chr11:50,409,042–50,422,316, 1 gene, copy number 26: AC024405.1.
- chr11:122,152,229–122,152,308, 1 gene, copy number 9: MIR100.
- chr12:28,505,394–28,505,528, 1 gene, copy number 11: RNA5SP355.
- chr14:21,918,188–21,924,651, 2 genes, copy number 15: TRAV13-2, TRAV14DV4.
- chr16:6,748,908–14,632,728, 161 genes, copy number 13–33 (within-gene range 6–33) (broad region; genes not listed).
- chr18:28,146,233–43,115,691, 161 genes, copy number 9–17 (within-gene range 8–17) (broad region; genes not listed).
- chr22:19,756,703–24,442,357, 341 genes, copy number 10–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 43. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
